Gene-level copy-number profile of tumor specimen ALCH-B1TH-TTP1-A from ALCHEMIST case ALCH-B1TH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.0 years (24,825 days).
Specimen ALCH-B1TH-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 44bb3cb8-9e3c-4db4-904c-3c51187da390.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1TH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/adcb8764-cf71-4e9a-86c7-fcdc339b0715

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 61; copy number 1: 9,541; copy number 2: 45,904; copy number 3: 3,196; copy number 4: 129; copy number 7: 79; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:219,418,377–219,493,629, 4 genes (within-gene range 0–2): DES, AC053503.3, AC053503.5, SPEG.
- chr2:232,343,116–232,487,834, 12 genes (within-gene range 0–2): NRBF2P6, ECEL1P3, AC068134.3, ALPP, AC068134.1, ECEL1P2, ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1.
- chr11:70,705,167–70,706,068, 2 genes (within-gene range 0–2): Y_RNA, AP000590.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 81 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:39,545,646–40,860,763, 25 genes, copy number 7 (within-gene range 3–7): AC011290.1, YAE1, AC011290.2, AC004837.3, AC004837.1, RALA, AC004837.2, LINC00265, RNU6-719P, AC004987.3, CICP22, AC004987.2, AC004987.1, SSBL3P1, RWDD4P2, RN7SL496P, AC072061.1, CDK13, AC006023.2, AC006023.1, MPLKIP, Y_RNA, SUGCT, THUMPD3P1, SUGCT-AS1.
- chr7:47,655,244–47,661,648, 1 gene, copy number 7: C7orf65.
- chr7:89,443,946–92,917,187, 53 genes, copy number 7: AC002383.1, RNU6-274P, STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1.
- chr14:105,093,609–105,100,131, 2 genes, copy number 8: LINC02298, AL512356.4.

Autosomal genes at a single copy (total copy number 1): 8,456. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
